Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25S, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25S-01A (Primary Tumor).

[page 1 of 2]
LABORATORY SERVICES

100-0-3

carcinoma, hepatocellular, NOS

Site: liver c22.0

8170/3

hw
4/25/11

Accession #:

Name:

Patient ID:

PHN:

ALT ID:

DOB:

Telephone:

Requesting Physician:

Encounter:

Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

ORIGINAL REPORT

SPECIMEN:

- A. Gallbladder.
- B. Right liver and diaphragm.

CLINICAL HISTORY:

Hypervascular lesion in right liver in segment 7.

DIAGNOSIS:

A. GALLBLADDER, CHOLECYSTECTOMY:

- CHRONIC CHOLECYSTITIS AND CHOLELITHIASIS.

B. RIGHT LIVER AND DIAPHRAGM, RESECTION:

- HEPATOCELLULAR CARCINOMA, MODERATELY DIFFERENTIATED (GRADE II/III).
- TUMOR SIZE: 12 X 9.6 X 2.4 CM.
- INVADING INTO PERI-HEPATIC ADIPOSE TISSUE.
- PERITUMORAL INTRAVASCULAR INVASION PRESENT.
- TWO SATELLITE NODULES IDENTIFIED.
- RESECTION MARGIN IS 1 MM FROM THE SATELLITE NODULE, HOWEVER SMALL CLUSTERS OF TUMOR CELLS PRESENT AT RESECTION MARGIN.
- BACKGROUND HEPATIC TISSUE SHOWING CIRRHOSIS AND PERIportal INFLAMMATION CONSISTING OF SIGNIFICANT NUMBERS OF PLASMA CELLS AND EOSINOPHILS.

Reported:

Reported by:

Signed by:

(Electronic Signature)

GROSS DESCRIPTION:

A. The specimen is received fresh and is subsequently placed into formalin, and consists of a dark tan intact gallbladder which measures 8.0 x 3.0 x 3.0 cm. The serosal surface is smooth and glistening. Opening the gallbladder reveals it to be filled with a thick green bile and contains round multifaceted calculi ranging in size from 0.1 cm up to 0.6 cm in greatest dimension. The mucosa surface is dark green, velvety and the gallbladder wall measures 0.2 cm in thickness. Found within the cystic duct are two brown

FINAL

[page 2 of 2]
LABORATORY SERVICES

Accession #:
Name:
Patient ID:
PHN:
ALT ID:
DOB:
Telephone:
Requesting Physician:
Encounter:
Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

GROSS DESCRIPTION:

multifaceted calculi measuring 0.2 cm in greatest dimension. Grossly the cystic duct lymph node is not identified. Three representative sections are submitted in one cassette.

B. The specimen is received fresh and is subsequently placed into formalin, and consists of a portion of liver weighing 859 g and measuring 15.0 x 12.0 x 8.0 cm. The resection margin of the specimen has been inked blue. Sectioning of the specimen reveals a lobulated necrotic mass occupying approximately 80% of the liver measuring 12 x 9.6 x 2.4 cm. The border of this mass has an ill-defined appearance and two small tan nodules are identified within the liver parenchyma adjacent to this large mass. Both these nodules measures 0.2 cm in greatest dimension. A prominent blood vessel is noted within the liver parenchyma that contains thrombus material. Grossly the liver capsule has a lobulated appearance due to invasion of the mass. Grossly the main mass comes to within approximately 1.5 cm of the blue painted margin. The liver capsule overlying the normal liver parenchyma has a slightly bumpy appearance ?cirrhosis. Sections of the specimen is as follows:

- B1. section of vessel with thrombus at blue painted margin
- B2-3. two random sections of blue painted margin
- B4-6. section of nodules on liver capsule
- B7. section of nodule on liver capsule and small nodule close to overlying blue painted margin, 0.2 cm
- B8-10. three sections from the large mass
- B11-12. two random sections from adjacent liver parenchyma
- B13. section of small nodule ?satellite lesion in liver parenchyma

MICROSCOPIC DESCRIPTION:

The hepatocellular carcinoma is composed of mainly trabecular and pseudoglandular pattern. The tumor cells are hyperchromatic with easily identifiable mitoses. Focal tumor necrosis is also present. There are peritumoral intravascular invasion. The tumor is focally infiltrating into the perihepatic adipose tissue (? diaphragm). The immunohistochemical stains demonstrate the nature of the hepatocellular origin. The tumor cells show canalicular stain for CEA and are strongly positive for Hep-par-1. They are negative for CK7, CK20, synaptophysin and AFP. The background hepatic tissue is cirrhotic. The etiology of cirrhosis cannot be determined. However, there are significant numbers of lymphoplasmacytes and eosinophils in the periportal area. The hepatocytes show no ground glass change or Mallory bodies.

Procedure:

Source: NCI Genomic Data Commons file 766fe03a-0ade-4a9c-9aac-c5ade285ddc8 (TCGA-G3-A25S.F4DAEF13-D4B0-4C12-9617-04878D3FC98D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).